CPTAC case C3L-01676 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3f0a6d27-8085-424c-926c-ee88b61ebadb

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Year of birth: 1963; Vital status: Alive.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 53.6 years (19,568 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M1; AJCC pathologic T: T2b; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: G3; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 1,193 days (3.3 years); Progression or recurrence: no; Days to last follow up: 1,193 days (3.3 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 11 cm (a second GDC size field records 2.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (3 entries)
- Days to follow up: 489 days (1.3 years); Disease response: Progressive Disease; Karnofsky performance status: 90; ECOG performance status: 0.
- Days to follow up: 489 days (1.3 years); Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 0.
- Days to follow up: 1,193 days (3.3 years); Disease response: With Tumor.

Other clinical attributes
- Weight: 88.45 kg; Height: 167.64 cm; BMI: 31.47.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01676-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 453 mg; Time between excision and freezing: 19 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01676-23: Section location: Middle; Percent tumor nuclei: 85; Percent necrosis: 2.
- Sample C3L-01676-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 31 mg; Time between excision and freezing: 19 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-01676-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 98 mg; Time between excision and freezing: 19 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-01676-72: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
